Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4K4, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4K4-01A (Primary Tumor).

[page 1 of 3]
DOB:

Sex: F

Physician:

Accession:

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) ESOPHAGEAL MUSCULARIS:

Skeletal muscle and fibroconnective tissue, no tumor present.

(B) PORTION OF RIGHT INFERIOR PARATHYROID GLAND:

Scant fragments of fibroadipose tissue, no tumor present.
No parathyroid tissue identified.

(C) SOFT TISSUE OF ANTERIOR TRACHEAL WALL:

PAPILLARY THYROID CARCINOMA IN FIBROCONNECTIVE TISSUE.

(D) LEFT NECK DISSECTION, LEVEL II:

Five lymph nodes, negative for tumor (0/5).

(E) LEFT NECK DISSECTION, LEVEL III:

METASTATIC PAPILLARY THYROID CARCINOMA IN FOUR OF EIGHT LYMPH NODES (4/8).
FOCAL EXTRATHYROIDAL EXTENSION IS PRESENT.

(F) LEFT NECK DISSECTION, LEVEL IV:

METASTATIC PAPILLARY THYROID CARCINOMA IN FIVE OF FIFTEEN LYMPH NODES (5/15).
EXTRANODAL EXTENSION IS PRESENT.

(G) BILATERAL PARATRACHEAL SUPERIOR MEDIASTINAL AND TOTAL THYROID CONTENTS:

PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Left lobe

Multi-focal: No

Size = 4.4 cm

Extrathyroidal extension: Present, extending into skeletal muscle

Lymphovascular invasion: Present

Resection Margins: Positive

Background Thyroid: Multinodular adenomatous goiter

Lymph nodes:

METASTATIC PAPILLARY THYROID CARCINOMA IN 4 OF 15 LYMPH NODES

Location: Periglandular and peritracheal

Extracapsular extension: Present

ICD-0-3
Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9

lw
10/4/12

GROSS DESCRIPTION

(A) ESOPHAGEAL MUSCULARIS – A (0.7 x 0.6 x 0.2 cm) portion of tissue. Entirely submitted for frozen section in A.
*FS/DX: NEGATIVE FOR TUMOR.

(B) PORTION OF RIGHT INFERIOR PARATHYROID GLAND – A less than 0.1 x less than 0.1 x less than 0.1 cm fragment of tissue. Entirely submitted for frozen section in B. Tissue may not survive processing.

[page 2 of 3]
DOB: _____
Physician: _____

Sex: F

Collected: _____
Received: _____

Pathologist: _____
Case type: Surgical Case

Accession: _____

***FS/DX: VERY MINUTE FRAGMENT OF FIBROCOLLAGENOUS TISSUE. NO PARATHYROID TISSUE IDENTIFIED.**

(C) **SOFT TISSUE OF ANTERIOR TRACHEAL WALL** – One fragment of pink soft tissue measuring (0.5 x 0.3 x 0.2 cm). Submitted in toto in cassette C.

(D) **LEFT NECK DISSECTION LEVEL 2** – One segment of fibroadipose tissue measuring (4.5 x 3 x 2 cm). Within this fragment, five possible lymph nodes are identified, the largest of which measures 4 cm in greatest dimension.

SECTION CODE: D1-D3, one lymph node, serially sectioned; D4, one lymph node, bisected; D5, three possible lymph nodes

(E) **LEFT NECK DISSECTION LEVEL 3** – One segment of fibroadipose tissue measuring (5 x 4 x 1 cm). Several lymph nodes are identified, the largest of which measures 2.2 cm in greatest dimension.

SECTION CODE: E1, representative section of one positive lymph node; E2, representative section of one positive lymph node; E3, one lymph node, serially sectioned; E4, four possible lymph nodes; E5, four possible lymph nodes.

(F) **LEFT NECK DISSECTION LEVEL 4** – One segment of fibroadipose tissue measuring (7 x 4 x 2 cm). Within this fragment is a large area of matted lymph nodes (5 cm in greatest dimension). Several other lymph nodes are also identified.

SECTION CODE: F1, F2, representative section of positive matted lymph nodes; F3, representative section of one positive lymph node; F4, one lymph node, bisected; F5, four possible lymph nodes; F6, five possible lymph nodes; F7, five possible lymph nodes.

(G) **BILATERAL PARATRACHEAL SUPERIOR MEDIASTINAL AND TOTAL THYROID CONTENTS** – A thyroidectomy specimen with bilateral paratracheal and superior mediastinal contents (overall 10.3 x 7.5 x 4.8 cm) with thyroid (7 x 6.3 x 4.5 cm) and associated anterior strap muscles bilaterally and fibroadipose tissue.

A (4.4 x 3.8 x 3 cm) variegated red-brown to white-tan focally papillary and cystic tumor nodule is present replacing approximately 80% of the left lobe of thyroid, abutting the isthmus. The tumor grossly abuts the posterior (tracheal) margin of resection.

A (2 x 1.5 x 1 cm) lymph node is present at the left lateral aspect of the left thyroid lobe (nodule #1). Six additional possible lymph nodes are identified within the paratracheal adipose tissue, ranging in size from 0.6 to 1.2 cm in greatest dimension.

Three nodules are identified within the anterior strap muscles and fibroadipose tissue, ranging in size from (2.4 x 1.8 x 1.5 cm, nodule #2, 2.3 x 1.7 x 1.3 cm nodule #3 and 1.5 x 1.3 x 0.7 cm nodule #4). An additional four possible lymph nodes, ranging in size from 0.5 to 0.9 cm are identified within this anterior fibroadipose tissue.

A portion of normal thyroid, tumor tissue and nodule #2 is submitted for tissue banking. Representative sections are submitted.

SECTION CODE: G1, G2, right lobe of thyroid, representative; G3, isthmus; G4-G11, left thyroid lobe with tumor (posterior tracheal margin in G7 and G10, cystic portion of tumor in G8, G9); G12, left paratracheal nodule (nodule #1), bisected; G13, six possible lymph nodes from left paratracheal region; G14, G15, nodule #2, from anterior soft tissue (harvested); G16, G17, nodule #3 from anterior soft tissue, representative; G18, nodule #4, bisected; G19, four possible lymph nodes from anterior soft tissues.

CLINICAL HISTORY

Papillary thyroid carcinoma.

SNOMED CODES

T-B6000, T-C4200, M-80503, M-Y3420, M-80506

Surgical Pathology Report		Page 2 of 3
File under: Pathology		

[page 3 of 3]
Collected: _____ Pathologist: _____ Physician: _____ Sex: F
Received: _____ Case type: Surgical Case Accession: _____

"Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Surgical Pathology Report		Page 3 of 3	
File under: Pathology			

Source: NCI Genomic Data Commons file d49de742-4299-4bbf-a740-a0fe5dfae090 (TCGA-EL-A4K4.19218996-6E11-4D0F-A09A-FCE3119185F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).